Somatic mutation profile of tumor specimen TARGET-10-PANWGG-09A (aliquot TARGET-10-PANWGG-09A-01D) from TARGET case TARGET-10-PANWGG, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.7 years (1,335 days).
Specimen TARGET-10-PANWGG-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3ea2891c-5af7-4923-a268-eefc871ccef7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PANWGG-10A (Blood Derived Normal), aliquot TARGET-10-PANWGG-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ede23366-f8c6-44f6-80e0-8e791d89a411

The open-access MAF lists 15 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 2, Intron 2, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 8/71 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARHGEF11 | c.1169G>A p.R390H | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs755424336; called by muse, mutect2, varscan2
- KCNC1 | c.641G>A p.R214H | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.513); catalogued as rs552970887; called by muse, mutect2, varscan2
- KDR | c.2865C>G p.I955M | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.328); catalogued as rs1239038856, COSV99816637; called by muse, mutect2, varscan2
- NDC80 | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.311); catalogued as COSV55248144; called by muse, mutect2, varscan2
- SLC6A5 | c.437C>A p.T146N | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.035); catalogued as rs759574943; called by muse, mutect2, varscan2
- CDKL5 | c.2978C>T p.S993F | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CSPP1 | c.1039G>C p.D347H (on ENST00000676605; = p.D306H on NM_024790.6) | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MAGI1 | c.4266C>A p.D1422E | Missense Mutation (SNP) | VAF 7/127 reads (6%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0.003); called by muse, mutect2
- RFX3 | c.628C>T p.R210* | Nonsense Mutation (SNP) | VAF 45/134 reads (34%) | called by muse, mutect2, varscan2
- ITGB7 | c.714C>T p.D238= | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as rs1415198191, COSV57238891; called by mutect2, varscan2
- SELL | c.474C>T p.D158= (on ENST00000650983; = p.D145= on NM_000655.5) | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as rs1022614911, COSV52550007; called by muse, mutect2, varscan2
- ADAMTS5 | c.*92G>A | 3'UTR (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2
- EIF4A3 | c.728+114C>T | Intron (SNP) | VAF 7/18 reads (39%) | catalogued as rs1043541067; called by mutect2, varscan2
- MLF2 | c.270+26C>T | Intron (SNP) | VAF 15/80 reads (19%) | catalogued as rs755928058, COSV99180129; called by muse, mutect2, varscan2
